Somatic mutation profile of tumor specimen TCGA-S6-A8JW-01A (aliquot TCGA-S6-A8JW-01A-11D-A435-10) from TCGA case TCGA-S6-A8JW, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 37.9 years (13,861 days).
Specimen TCGA-S6-A8JW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24c622bd-08ee-4178-9818-12712ae74800.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S6-A8JW-10A (Blood Derived Normal), aliquot TCGA-S6-A8JW-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32d53f97-4212-402f-bde0-8c9f5530f54c

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Frame Shift Del 1, Nonsense Mutation 1, In Frame Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 52/176 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GPR179 | c.3534_3536del p.E1178del (on ENST00000621958; = p.E1177del on NM_001004334.4) | In Frame Del (DEL) | VAF 10/79 reads (13%) | catalogued as rs1567723525; called by pindel, varscan2
- ADAM17 | c.874A>C p.K292Q | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CAD | c.2965C>G p.L989V | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL2RB | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- MRPL3 | c.233_234del p.C78Sfs*5 | Frame Shift Del (DEL) | VAF 42/180 reads (23%) | called by pindel, varscan2
- PHF3 | c.5590C>T p.Q1864* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- ZNF296 | c.1270G>C p.A424P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- SCAF1 | c.303G>A p.V101= | Silent (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
